HCMI case HCM-WCMC-0949-C67 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d8522fe4-e14f-46de-ab9d-f7445099d5a5

Demographics
Sex at birth: female; Year of birth: 1936; Vital status: Alive.

Diagnoses (1)
1. Papillary transitional cell carcinoma, non-invasive: ICD-O-3 morphology code: 8130/2; ICD-10 code: C67.8; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Overlapping lesion of bladder; Classification of tumor: primary; Age at diagnosis: 82.5 years (30,133 days); Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Days to follow up: 42 days; Disease response: Stable Disease; Progression or recurrence: No.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 63.5 kg; Height: 149.9 cm; BMI: 28.
- Timepoint category: Prior to Diagnosis; Comorbidities: Urinary Tract Infection; Risk factors: Urinary Tract Infection.

Exposures
- Tobacco smoking status: Current Smoker; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-WCMC-0949-C67-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-WCMC-0949-C67-01A-01-S1-HE: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-WCMC-0949-C67-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 35; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 10; Percent stromal cells: 45; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-WCMC-0949-C67-12A: Sample type: Saliva; Tissue type: Normal; Specimen type: Saliva; Preservation method: Frozen.
- Sample HCM-WCMC-0949-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
